CCDI case PBCIAA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3c97c1c6-8182-4ae8-a803-999c07ab030c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 13.9 years (5,066 days).

Biospecimens (3 samples)
- Samples 0DSEKN, 0DSEL7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEKY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
